Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A6R0, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A6R0-01A (Primary Tumor).

Patient ID:

Surgical Date:

Gross Description: There is a skin flap up to 8 x 4 cm in size with a mushroom-like pigmented formation up to 2 x 2 x 1 cm in size, with ulceration. Tumor is on the thin leg.

Microscopic Description: Malignant melanoma of the skin, pigmented, with ulceration. Clark's level is IV. Breslow tumor thickness is 10 mm. There is perifocal lymphoid infiltration.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: More than 4 mm with or without ulceration, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, trunk

Tumor size: 2 x 1 x 2 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Skin of back, pigmented, ulcerated. Clark's level is IV. Breslow tumor thickness is 10 mm.

Comments: None

ICD-O-3
Melanoma, malignant NOS
8720/3
Site ^{CSCF} Skin NOS C44.9
path
Skin trunk C44.5
Qx 7/5/13

Source: NCI Genomic Data Commons file c9ceaaf5-c00f-4058-992e-022ce0b6baad (TCGA-EB-A6R0.95E9EB7F-81A7-4A4F-848B-59D1710E024A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).